Somatic mutation profile of tumor specimen MBCProject_4989_T2_WES (aliquot MBCProject_4989_T2_WES_1) from CMI case MBCProject_4989, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 49.7 years (18,150 days).
Specimen MBCProject_4989_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecac9bda-29eb-4d68-9c49-0047795231c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4989_SALIVA (Saliva), aliquot MBCProject_4989_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/150ecd48-57a0-4d99-9b9d-60b07e8c07bd

The open-access MAF lists 39 somatic variants for this specimen: 33 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 4, Splice Site 3, Intron 2, Nonsense Mutation 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 108/306 reads (35%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 35/111 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+2T>C p.X187_splice | Splice Site (SNP) | VAF 120/250 reads (48%) | hotspot (GDC flag); catalogued as CS114004, COSV52709511, COSV52900265, COSV53486980, COSV99478821; called by muse, mutect2, varscan2
- ABCA4 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 75/385 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV64674068; called by muse, mutect2, varscan2
- ACHE | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.024); catalogued as rs763331269; called by muse, mutect2, varscan2
- CREB3L3 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.344); catalogued as rs999506735; called by muse, mutect2, varscan2
- CSMD2 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.72); catalogued as rs771670995; called by muse, varscan2
- FOXRED2 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs767729716; called by muse, mutect2, varscan2
- KIRREL3 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1431156299; called by muse, mutect2
- PIGU | c.1102C>T p.L368F | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs748672869; called by muse, mutect2, varscan2
- ROCK1 | c.3035G>A p.R1012Q | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67694577; called by muse, mutect2, varscan2
- SOX9 | c.791G>C p.R264T | Missense Mutation (SNP) | VAF 258/395 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV55421835, COSV55423870; called by muse, mutect2, varscan2
- TRPC3 | c.655G>A p.D219N (on ENST00000379645 / NM_001366479.2; = p.D146N on NM_003305.2) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs868073711, COSV53371571; called by muse, mutect2, varscan2
- WDR38 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774718388; called by muse, mutect2, varscan2
- AKAP13 | c.1589A>C p.K530T | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ASH1L | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 119/323 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BICDL1 | c.543G>T p.L181F | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C8orf34 | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CPNE7 | c.1442A>T p.Q481L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- DENND4B | c.2039C>T p.T680I | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GALNT2 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- INPP5D | c.2674C>T p.Q892* (on ENST00000445964 / NM_001017915.3; = p.Q891* on NM_005541.5) | Nonsense Mutation (SNP) | VAF 70/228 reads (31%) | called by muse, mutect2, varscan2
- KCNU1 | c.1708C>G p.L570V | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- KCNU1 | c.1819C>A p.H607N | Missense Mutation (SNP) | VAF 49/374 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- POGZ | c.820T>G p.S274A | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- PRDM8 | c.433T>C p.S145P | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- QRICH1 | c.1615G>C p.E539Q | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); called by muse, varscan2
- SLC22A2 | c.1100T>C p.M367T | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TMPRSS15 | c.2125A>G p.T709A | Missense Mutation (SNP) | VAF 117/441 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRAV38-1 | c.310_312dup p.L104dup | In Frame Ins (INS) | VAF 10/49 reads (20%) | called by mutect2, pindel
- TSSK3 | c.410G>A p.C137Y | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC3 | c.1444-2A>T p.X482_splice | Splice Site (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- UTP20 | c.5025-5_5025-1delinsTTTTT p.X1675_splice | Splice Site (ONP) | VAF 8/99 reads (8%) | called by mutect2*, pindel
- BTBD7 | c.2841C>T p.D947= | Silent (SNP) | VAF 37/222 reads (17%) | called by muse, varscan2
- FSTL5 | c.12C>T p.C4= | Silent (SNP) | VAF 27/188 reads (14%) | catalogued as rs751509814; called by muse, mutect2, varscan2
- LRRC26 | c.516C>T p.L172= | Silent (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- SALL1 | c.405C>T p.S135= | Silent (SNP) | VAF 174/466 reads (37%) | catalogued as rs777331005, COSV51765337, COSV99171628; called by muse, mutect2, varscan2
- SPEG | c.2882-1085C>A | Intron (SNP) | VAF 52/159 reads (33%) | called by muse, mutect2, varscan2
- STAG1 | c.902+49T>C | Intron (SNP) | VAF 57/171 reads (33%) | catalogued as rs751638233; called by muse, mutect2, varscan2
